Gene-level copy-number profile of tumor specimen ALCH-B3FX-TTP1-A from ALCHEMIST case ALCH-B3FX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 51.0 years (18,638 days).
Specimen ALCH-B3FX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dc750389-9fbf-49f9-8a82-d0034cb31bb9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3FX-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/5cacea78-3b8e-448b-9c69-7a6806e13b4d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 53; copy number 1: 528; copy number 2: 14,864; copy number 3: 1,905; copy number 4: 40,956; copy number 5: 364; copy number 6: 147; copy number 7: 32; copy number 12: 7; copy number 14: 8; copy number 16: 41; copy number 20: 4.

Homozygous deletions (total copy number 0; autosomes only): 53 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:156,893,698–156,916,434, 1 gene: PEAR1.
- chr2:131,833,783–131,836,532, 1 gene: AC103564.2.
- chr3:133,746,040–133,796,641, 2 genes (within-gene range 0–2): TF, AC080128.1.
- chr9:136,428,619–136,439,845, 1 gene: INPP5E.
- chr9:136,494,433–136,546,048, 3 genes (within-gene range 0–1): NOTCH1, MIR4673, AL592301.1.
- chr9:136,844,415–136,860,799, 3 genes (within-gene range 0–2): AJM1, PHPT1, MAMDC4.
- chr12:44,508,275–46,270,017, 23 genes: NELL2, Y_RNA, DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3.
- chr12:61,231,159–62,279,150, 8 genes (within-gene range 0–4): AC090017.1, DUX4L52, TAFA2, RPL21P104, KRT8P19, RPS3P6, AC078789.1, KLF17P1.
- chr14:104,681,146–104,747,325, 3 genes (within-gene range 0–2): INF2, AL583722.3, ADSS1.
- chr16:1,431,078–1,446,519, 4 genes (within-gene range 0–3): PERCC1, CCDC154, AL032819.2, AL031600.3.
- chr20:63,939,829–63,956,985, 4 genes (within-gene range 0–4): UCKL1, MIR1914, MIR647, UCKL1-AS1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 60 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:68,248,242–69,855,363, 48 genes, copy number 12–16 (within-gene range 7–16): IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2.
- chr12:70,443,784–71,032,083, 8 genes, copy number 14: RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1.
- chr12:72,727,923–73,208,317, 4 genes, copy number 20: AC133480.1, AC090503.2, LINC02444, AC090503.1.

Autosomal genes at a single copy (total copy number 1): 16. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
